TCGA case TCGA-DE-A69K — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: University of North Carolina. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7f9fad75-ac3e-4580-b949-80eed07a3230

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 58.6 years (21,403 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 434 days (1.2 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Extrathyroid extension: Minimal (T3); Lymph nodes positive: 0; Lymph nodes tested: 4; Measurement unit: Centimeters; Tumor depth measurement: 1.2; Tumor length measurement: 3.1; Tumor width measurement: 1.8.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 91 days; Days to treatment end: 91 days; Treatment dose: 125 mCi; Treatment outcome: Partial Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 125 mCi; Pretreatment: Thyroxine Withdrawal.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 125; Prescribed dose units: mCi; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.

Follow-up (5 entries)
- Days to follow up: 98 days; Disease response: With Tumor.
- Day 434 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 434 days (1.2 years).
- Imaging type: Ultrasound; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Disease response: Persistent Locoregional Disease; Timepoint: Within 3 Months of Surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DE-A69K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 330 mg.
  Slide TCGA-DE-A69K-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DE-A69K-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DE-A69K-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No; I 131 radiation first treatment dose: 125 mCi; I 131 radiation treatment cumulative dose: 125 mCi; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: Persistent locoregional disease; New tumor event diagnosis indicator: No.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT with contrast.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: Biochemical evidence of disease; New tumor event diagnosis confirmed by: Imaging.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 434 days; disease-specific survival: no event (censored), 434 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 434 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DE-A69K-01A-11D-A396-01): tumor purity 0.83, ploidy 2, whole-genome doublings 0.
